Somatic mutation profile of tumor specimen TCGA-CJ-4640-01A (aliquot TCGA-CJ-4640-01A-02D-1386-10) from TCGA case TCGA-CJ-4640, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 49.8 years (18,178 days).
Specimen TCGA-CJ-4640-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0df23bc-aa42-40f0-96ea-649b00f7f514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4640-11A (Solid Tissue Normal), aliquot TCGA-CJ-4640-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/446d2ddb-e859-4b63-bd1d-86adbafd6c51

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Frame Shift Del 5, In Frame Del 2, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM28 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV56099655; called by muse, mutect2, varscan2
- ANK2 | c.10943T>A p.L3648H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52156031; called by muse, mutect2, varscan2
- B3GALNT2 | c.1086C>A p.D362E | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64003674; called by muse, mutect2, varscan2
- CALR | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.852); catalogued as COSV57122514; called by muse, mutect2, varscan2
- CBLB | c.2651G>T p.R884I | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51424898, COSV51427825; called by muse, mutect2, varscan2
- CFAP70 | c.886A>G p.S296G | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as rs1419739493, COSV60282497; called by muse, mutect2, varscan2
- DAAM1 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV100658206, COSV62835637; called by muse, mutect2, varscan2
- DNAH7 | c.6488C>A p.A2163E | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56759879; called by muse, varscan2
- DNAH7 | c.6487G>A p.A2163T | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV56759891; called by muse, varscan2
- DSC2 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs765948147, COSV51863406; called by muse, mutect2, varscan2
- DSG1 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV57134541; called by muse, mutect2, varscan2
- IFNL2 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV59593315; called by muse, mutect2, varscan2
- LRFN2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766641009, COSV57826093; called by muse, mutect2, varscan2
- LRP2 | c.11311T>C p.C3771R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55549181; called by muse, mutect2
- LRP4 | c.4573G>C p.D1525H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV101066885, COSV66135258; called by muse, mutect2, varscan2
- NAP1L4 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV65880966; called by muse, mutect2, varscan2
- NAPSA | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); catalogued as rs958024903, COSV53797179; called by muse, varscan2
- NIF3L1 | c.957G>T p.M319I (on ENST00000409020 / NM_001369444.1; = p.M292I on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV62900116; called by muse, mutect2, varscan2
- NOP2 | c.648G>T p.E216D (on ENST00000322166 / NM_001258308.2; = p.E212D on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV59110132; called by muse, mutect2, varscan2
- NPAS4 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749883401, COSV60649002; called by mutect2, varscan2
- RGCC | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.413); catalogued as rs747775886, COSV65058158; called by muse, mutect2, varscan2
- RNF40 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV61214389; called by muse, mutect2, varscan2
- RPL19 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56635077; called by muse, mutect2, varscan2
- SHMT1 | c.615C>A p.Y205* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57398533; called by muse, mutect2, varscan2
- SIGLEC8 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV58473184, COSV58475837; called by muse, mutect2, varscan2
- SNX33 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57913240; called by muse, mutect2, varscan2
- SRRT | c.1545G>C p.Q515H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV53816754; called by muse, mutect2, varscan2
- TRIM25 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV57543832; called by muse, mutect2, varscan2
- UMOD | c.1325T>C p.M442T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1313997403, COSV56774969; called by muse, mutect2, varscan2
- ZCCHC8 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV60317886; called by muse, mutect2, varscan2
- ZNF132 | c.1676T>A p.I559N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV54234651; called by muse, mutect2, varscan2
- ZNF714 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV52511033; called by muse, mutect2, varscan2
- AMIGO2 | c.192del p.N65Tfs*5 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- BCAT2 | c.225_248del p.W75_F83delinsC | In Frame Del (DEL) | VAF 8/97 reads (8%) | called by mutect2, pindel
- DIPK1C | c.1064_1078del p.R355_A360delinsP | In Frame Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ELOC | c.334del p.C112Vfs*3 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- HEATR5A | c.3917T>C p.V1306A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KIZ | c.1042+2_1042+4del p.X348_splice | Splice Site (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- LYST | c.7118dup p.N2373Kfs*36 | Frame Shift Ins (INS) | VAF 35/132 reads (27%) | called by mutect2, pindel, varscan2
- NOM1 | c.1468del p.L490* | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
- PPP4R3B | c.1459_1466del p.C487Gfs*10 (on ENST00000616407 / NM_001122964.3; = p.C487Gfs*2 on NM_020463.4) | Frame Shift Del (DEL) | VAF 39/310 reads (13%) | called by mutect2, pindel, varscan2
- ZGPAT | c.1194_1216del p.C398Wfs*11 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- CERS2 | c.678C>A p.A226= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV54980738; called by muse, mutect2, varscan2
- DICER1 | c.4128C>A p.P1376= | Silent (SNP) | VAF 9/218 reads (4%) | catalogued as COSV58618147; called by muse, mutect2
- DPP10 | c.2139C>A p.G713= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV59679636; called by muse, mutect2, varscan2
- ENTHD1 | c.630C>T p.C210= | Silent (SNP) | VAF 27/207 reads (13%) | catalogued as rs1464681637, COSV57317414; called by muse, mutect2, varscan2
- GPATCH11 | c.663A>G p.E221= (on ENST00000409774; = p.E199= on NM_174931.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV56135035; called by mutect2, varscan2
- GPR52 | c.909C>A p.T303= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV52288822; called by muse, mutect2, varscan2
- IQGAP2 | c.1143C>G p.A381= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as COSV57171872; called by muse, mutect2
- JAK3 | c.267C>A p.S89= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs754716735, COSV71685921; called by muse, mutect2, varscan2
- PELI2 | c.552G>T p.G184= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV50710718; called by muse, mutect2, varscan2
- RRP12 | c.3501A>G p.E1167= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs1564749534, COSV59666861; called by muse, mutect2, varscan2
- TMEM222 | c.129C>T p.V43= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV65027061; called by muse, mutect2, varscan2
- TRPM3 | c.979+17819G>T | Intron (SNP) | VAF 20/111 reads (18%) | catalogued as COSV62469170; called by muse, mutect2, varscan2
